Somatic mutation profile of tumor specimen MP2PRT-PATDAG-TMP1-A (aliquot MP2PRT-PATDAG-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATDAG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,386 days).
Specimen MP2PRT-PATDAG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d91ff735-aac9-4d34-967b-9d43553530c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDAG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDAG-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae38fb0c-d9e3-4043-9e21-b006cb74f0d5

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF12 | c.3095G>A p.R1032K | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV63104617; called by muse, mutect2
- CHPF | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 221/480 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370676153; called by muse, mutect2, varscan2
- CTNNA2 | c.1154T>C p.M385T | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs759844097; called by muse, mutect2
- GTF3C1 | c.4774G>A p.V1592M | Missense Mutation (SNP) | VAF 140/362 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751732275, COSV62240836; called by muse, mutect2, varscan2
- ATP13A1 | c.3509A>C p.K1170T | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- B4GALT4 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DRP2 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 99/461 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GPRASP1 | c.1194G>T p.R398S | Missense Mutation (SNP) | VAF 218/562 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- PAGE1 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 182/448 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A15 | c.613T>A p.Y205N | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TRAF4 | c.1326_1327insT p.Q443Sfs*12 | Frame Shift Ins (INS) | VAF 121/342 reads (35%) | called by mutect2, varscan2
- DGKH | c.1578A>G p.V526= | Silent (SNP) | VAF 111/247 reads (45%) | called by muse, mutect2, varscan2
- DNAH5 | c.10582C>T p.L3528= | Silent (SNP) | VAF 28/362 reads (8%) | called by muse, mutect2
- KCTD1 | c.657C>T p.G219= | Silent (SNP) | VAF 36/503 reads (7%) | catalogued as rs147722648; called by muse, mutect2
- RAB44 | c.2124G>A p.S708= | Silent (SNP) | VAF 171/446 reads (38%) | catalogued as rs957867912; called by muse, mutect2, varscan2
